Somatic mutation profile of tumor specimen TCGA-E1-A7Z6-01A (aliquot TCGA-E1-A7Z6-01A-11D-A34J-08) from TCGA case TCGA-E1-A7Z6, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.0 years (14,985 days).
Specimen TCGA-E1-A7Z6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29c182d7-9998-43d6-b30b-e583f1475fff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7Z6-10A (Blood Derived Normal), aliquot TCGA-E1-A7Z6-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/335e12b5-e2a9-4792-b934-aed6db4ebc96

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 12, Silent 8, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 22/26 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ACSM5 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as COSV100089297; called by muse, mutect2, varscan2
- DSG2 | c.684C>A p.D228E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853387; called by muse, mutect2, varscan2
- MTMR8 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV100878503, COSV66396251; called by muse, varscan2
- OR10J5 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV100604765; called by muse, mutect2, varscan2
- PRRC2A | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs1464925342, COSV101051305; called by muse, mutect2, varscan2
- RPP40 | c.267A>T p.K89N | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV100124088; called by muse, mutect2
- RTL4 | c.713T>C p.L238S | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.082); catalogued as COSV100466068; called by muse, mutect2, varscan2
- RTL5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV65454159; called by muse, mutect2
- SMARCD3 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 105/208 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100063434; called by muse, mutect2, varscan2
- UROD | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1483459837, CM013617, COSV99870361; called by muse, mutect2, varscan2
- ATRX | c.1278_1279del p.N428Yfs*5 | Frame Shift Del (DEL) | VAF 108/388 reads (28%) | called by pindel, varscan2
- SUPT20HL2 | c.625T>G p.C209G | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CACYBP | c.216G>A p.T72= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs759751331, COSV100871637; called by muse, mutect2, varscan2
- DOLK | c.909T>C p.Y303= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as rs1244007975, COSV100455217; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM181B | c.255C>G p.G85= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100235131; called by muse, mutect2, varscan2
- IGHG3 | c.630C>T p.D210= | Silent (SNP) | VAF 99/268 reads (37%) | catalogued as rs371415797; called by muse, mutect2, varscan2
- MORC4 | c.444T>C p.V148= | Silent (SNP) | VAF 91/223 reads (41%) | catalogued as rs1175649227, COSV99717466; called by muse, mutect2, varscan2
- NUP107 | c.315G>C p.L105= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99971955; called by muse, mutect2
- PTPRD | c.4875G>A p.L1625= | Silent (SNP) | VAF 84/211 reads (40%) | catalogued as rs1249741113, COSV100645987; called by muse, mutect2, varscan2
- SGCZ | c.267G>A p.K89= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101166422; called by muse, mutect2, varscan2
